Gene-level copy-number profile of tumor specimen TCGA-AO-A0JL-01A from TCGA case TCGA-AO-A0JL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 59.9 years (21,895 days).
Specimen TCGA-AO-A0JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.cb51709b-1103-435b-b9da-eb362eae58fe.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 6,214 have no estimate.
https://portal.gdc.cancer.gov/files/52e688ea-db15-4b17-a61d-d48120ba1aab

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 563; copy number 3: 3,114; copy number 4: 19,114; copy number 5: 7,762; copy number 6: 9,523; copy number 7: 4,287; copy number 8: 4,388; copy number 9: 701; copy number 10: 796; copy number 11: 478; copy number 12: 1,771; copy number 13: 446; copy number 14: 830; copy number 16: 146; copy number 17: 480; copy number 18: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AO-A0JL-01): tumor purity 0.64, ploidy 5.82, whole-genome doublings 2 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 5,658 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,903,318–241,677,376, 2,159 genes, copy number 11–12 (broad region; genes not listed).
- chr1:243,124,428–247,761,255, 106 genes, copy number 10–16 (within-gene range 4–16) (broad region; genes not listed).
- chr4:53,377,839–54,295,272, 2 genes, copy number 9 (within-gene range 6–9): AC058822.1, LNX1.
- chr4:53,575,713–58,118,070, 96 genes, copy number 9 (broad region; genes not listed).
- chr4:58,780,626–60,038,586, 13 genes, copy number 10: AC017091.1, LINC02619, LINC02429, AC097501.1, AC108517.2, AC108517.1, Y_RNA, AC096588.1, AC093857.1, Y_RNA, RNU6-1325P, AC092596.1, AC097655.1.
- chr4:92,303,966–100,880,126, 83 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr5:4,436,850–4,440,259, 1 gene, copy number 10: AC106799.3.
- chr5:158,173,601–158,588,546, 10 genes, copy number 16: AC025437.5, AC025437.4, AC025437.6, AC025437.3, AC025437.2, AC025437.1, LINC02227, AC091979.1, AC091979.2, AC091939.1.
- chr5:169,552,449–173,961,980, 92 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr8:34,174,886–35,093,509, 7 genes, copy number 12: AC087855.2, AC090993.1, AC087855.1, RPL10AP3, LINC01288, AC087343.1, AC099685.1.
- chr8:35,254,344–35,256,605, 1 gene, copy number 12: AC090740.1.
- chr8:39,743,735–115,809,673, 1,127 genes, copy number 13–17 (within-gene range 4–17) (broad region; genes not listed).
- chr8:115,950,511–144,261,940, 445 genes, copy number 13 (within-gene range 4–13) (broad region; genes not listed).
- chr10:274,190–17,911,164, 305 genes, copy number 9 (broad region; genes not listed).
- chr14:20,029,399–21,634,940, 111 genes, copy number 10–12 (broad region; genes not listed).
- chr16:7,726,841–10,694,930, 56 genes, copy number 10–18: AC005774.1, AC093515.1, AC018767.2, LINC02152, AC018767.3, AC018767.1, AC074052.1, AC074052.2, TMEM114, AC138420.1, METTL22, AC007224.2, ABAT, RN7SL743P, RNU7-63P, AC007224.1, TMEM186, PMM2, AC012173.1, AC022167.2, CARHSP1, AC022167.1, AC022167.4, LITAFD, USP7, AC022167.3, AC087190.2, C16orf72, AC087190.3, AC087190.1, RPL21P119, LINC02177, AC012178.1, LINC01177, LINC01195, AC007221.1, RNA5SP403, RNA5SP404, AC007218.1, GRIN2A, AC007218.2, AC007218.3, AC133565.1, IMPDH1P11, AC022168.1, RN7SL493P, ATF7IP2, AC131649.1, AC131649.2, RNU6-633P, LINC01290, EMP2, AC027277.1, AC027277.2, TEKT5, AC007595.1.
- chr16:11,833,850–13,779,760, 35 genes, copy number 12: RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4, SNX29, AC007216.1, RPS23P6, AC007601.1, AC007601.2, AC092365.1, AC007598.2, AC007598.1, AC007598.3, AC131391.1, AC010333.1, AC010333.2, AC010333.3, CPPED1, MIR4718, AC109597.1, AC109597.2, AC092324.1, RPL35AP34, SHISA9, AC009134.1, U91319.1, AC003009.1, TMF1P1, U95743.1.
- chr17:34,725,509–39,567,559, 211 genes, copy number 9–14 (broad region; genes not listed).
- chr17:39,757,718–41,734,644, 136 genes, copy number 14 (within-gene range 4–14) (broad region; genes not listed).
- chr18:316,737–33,441,101, 572 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr18:60,495,868–63,981,774, 52 genes, copy number 9 (within-gene range 5–9): AC010928.2, MRPS5P4, AC010928.3, AC010928.1, AC113137.1, CTBP2P3, HMGN1P31, CDH20, RNU6-116P, RPL30P14, AC090409.2, AC090409.1, AC105094.2, AC105094.1, LINC01544, RNF152, PIGN, RPIAP1, RELCH, AC027514.1, AC027514.2, TNFRSF11A, Y_RNA, AC100843.1, RPL17P44, AC100843.2, ACTBP9, ZCCHC2, AC064801.1, AC064801.2, RN7SL705P, PHLPP1, RNU6-142P, BCL2, AC022726.1, AC022726.2, KDSR, AC036176.1, VPS4B, AC036176.2, SERPINB5, AC036176.3, ATP5MC1P6, SERPINB12, SERPINB13, SERPINB4, SERPINB11, SERPINB3, SERPINB7, SERPINB2, SERPINB10, HMSD.
- chr19:28,683,071–30,228,715, 38 genes, copy number 16: AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
